Surgical pathology report (de-identified scan), TCGA case TCGA-HU-8610, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-8610-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: Stomach cancer

GROSS:

Specimen submitted: Subtotal gastrectomy, fresh
Measurement: Greater curvature 20.5 cm
Lesser curvature 12.0 cm
Proximal resection margin 14.0 cm
Distal resection margin 6.5 cm
Duodenum 2.0 cm

Tumor location:

Stomach: Middle 1/3 (body), posterior wall,
From proximal resection margin - 4.0 cm
From distal resection margin - 6.0 cm

Tumor size: 3.8 x 2.5 x 2.0 cm

Tumor type: EGC I

Gross serosal invasion: No

Gross photo: Present

Blocks

T1-8 and T1B, tumor and surrounding tissue x 9

A, antral mucosa x 1

B and NB, body mucosa x 2

P, proximal resection margin x 1

D, distal resection margin x 1

LN1-4, superior gastric lymph nodes x 4

LN5-8, inferior gastric lymph nodes x 4

LN9, '5' lymph nodes x 1

LN10, '6' lymph nodes x 1

LN11, '7' lymph nodes x 1

LN12, '8' lymph nodes x 1

LN13, '9' lymph nodes x 1

LN14, '11p' lymph nodes x 1

MICROSCOPIC:

Tumor type: Adenocarcinoma - tubular, moderately differentiated

Depth of tumor invasion:

T1: T1b-Submucosa middle 1/3 (SM2)

Margins:

Proximal resection margin (-)

ICD-O-3

Adenocarcinoma, tubular 8211/3
Adenocarcinoma, intestinal tubular
8144/3 8211/3

Code to highest 8211/3

Site: Body of stomach C16.2
p25/16/14

[page 2 of 3]
=====

Distal resection margin (-)
Lauren classification: Intestinal
Lymphoid reaction: Absent
Lymphovascular invasion: Absent
Venous (large vessel) invasion: Absent
Perineural invasion: Absent
Lymph node metastases:
NO: No regional lymph node metastasis
number of involved nodes 0 total number of nodes 79
perinodal extension: No
Distant metastasis(M): Cannot evaluate
Pathologic stage: pT1bNOMx (AJCC 7th edition)

SPECIAL STAIN:

Cresyl Violet stain reveals no H. pylori.

NOT reported. Gross:

Stomach, prepylorus, scopic, chronic gastritis
Stomach, body, scopic, chronic gastritis, ulcer, intestinal metaplasia

Large intestine, sigmoid colon, scopic, tubular adenoma, low grade,
dysplasia
Large intestine, rectum, scopic, tubular adenoma, low grade, dysplasia

DIAGNOSIS:

Stomach, subtotal gastrectomy:
Adenocarcinoma, moderately differentiated
(early gastric cancer)

Lymph node, perigastric, subtotal gastrectomy:
Superior gastric: No tumor present (0/28)
Inferior gastric: No tumor present (0/33)

Lymph node, regional, biopsy:

[page 3 of 3]
Labeled '5': No tumor present (0/3)
Labeled '6': No tumor present (0/4)
Labeled '7': No tumor present (0/3)
Labeled '8': No tumor present (0/1)
Labeled '9': No tumor present (0/3)
Labeled '11p': No tumor present (0/4)

Originally an IBC
case.

EPC case - reviewed
by NC# BCR.

Source: NCI Genomic Data Commons file f1814eb8-0497-45fb-8559-8ff6d6d42eb4 (TCGA-HU-8610.24893DA8-DBBB-40E0-B42C-2011D0C47F81.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).